Somatic mutation profile of tumor specimen 1105260 (aliquot 7316UP-421-1105260) from CPTAC case C231855, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen 1105260: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e80a2aa9-443f-409b-8705-46390a1574af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105288 (Blood Derived Normal), aliquot 7316UP-421-1105288; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c90a9f76-d9f0-4040-886d-36964bb08f30

The open-access MAF lists 60 somatic variants for this specimen: 40 protein-altering or splice-affecting, 18 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 18, Frame Shift Del 3, Splice Site 2, In Frame Del 1, Splice Region 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RB1 | c.1215+1G>A p.X405_splice | Splice Site (SNP) | VAF 21/110 reads (19%) | hotspot (GDC flag); catalogued as rs587776783, CS890133, CS982341, COSV57294684, COSV57294939, COSV57306748; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AHNAK2 | c.10157G>A p.G3386D | Missense Mutation (SNP) | VAF 70/587 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.025); catalogued as rs199830560; called by muse, mutect2, varscan2
- ALOX15B | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 33/270 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs749072236; called by muse, mutect2, varscan2
- ARGFX | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 18/108 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs770818565, COSV100544207; called by muse, mutect2, varscan2
- ATP6V1C2 | c.1157G>A p.R386Q (on ENST00000272238 / NM_001039362.2; = p.R340Q on NM_144583.4) | Missense Mutation (SNP) | VAF 26/186 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.108); catalogued as rs1179657289, COSV55353294; called by muse, mutect2, varscan2
- B2M | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 65/535 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as rs368160918; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- E4F1 | c.1981G>A p.E661K | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.358); catalogued as rs540780876; called by muse, mutect2
- HOXD13 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs927690691, CM127648; called by muse, mutect2, varscan2
- LRRFIP1 | c.42_45del p.C14* | Frame Shift Del (DEL) | VAF 19/181 reads (10%) | catalogued as rs769674928; called by mutect2, pindel, varscan2
- MX2 | c.1300G>A p.E434K | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.89); PolyPhen benign (0.227); catalogued as rs745448850, COSV58096513; called by muse, mutect2, varscan2
- NAP1L2 | c.663G>C p.E221D | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs762791552; called by muse, mutect2, varscan2
- PKP2 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 46/247 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.017); catalogued as rs148480056, CM132691, COSV50730692; called by muse, mutect2, varscan2
- RFX6 | c.504G>A p.K168= | Splice Region (SNP) | VAF 38/286 reads (13%) | catalogued as COSV60583869; called by muse, mutect2, varscan2
- SCN5A | c.5755C>T p.R1919C (on ENST00000333535 / NM_198056.3; = p.R1918C on NM_000335.5) | Missense Mutation (SNP) | VAF 37/335 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs199473328, COSV100351290; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC17A9 | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 31/236 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.324); catalogued as rs201493327, COSV64847130; called by muse, mutect2, varscan2
- SPATA16 | c.989C>A p.P330Q | Missense Mutation (SNP) | VAF 40/272 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63532145, COSV63532636; called by muse, varscan2
- TERT | c.1604G>A p.R535H | Missense Mutation (SNP) | VAF 45/362 reads (12%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.689); catalogued as rs768398955, COSV57205187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRAK1 | c.606_608del p.S203del (on ENST00000327628 / NM_001349247.2; = p.S145del on NM_014965.5) | In Frame Del (DEL) | VAF 14/116 reads (12%) | catalogued as rs1559899029; called by pindel, varscan2
- ZDHHC1 | c.917G>A p.R306Q | Missense Mutation (SNP) | VAF 24/222 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as rs145809493; called by muse, mutect2
- AKAP7 | c.180G>C p.K60N | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- APOBEC1 | c.16+2T>G p.X6_splice | Splice Site (SNP) | VAF 21/191 reads (11%) | called by muse, mutect2, varscan2
- ATP5MC3 | c.124T>G p.S42A | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, varscan2
- BTBD7 | c.2322C>A p.N774K | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CDK3 | c.517A>C p.I173L | Missense Mutation (SNP) | VAF 34/331 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- CHD6 | c.1047G>T p.K349N | Missense Mutation (SNP) | VAF 30/299 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- DCT | c.1094T>G p.V365G | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DLL3 | c.40G>C p.V14L | Missense Mutation (SNP) | VAF 41/363 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM131B | c.437T>C p.M146T | Missense Mutation (SNP) | VAF 25/149 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- GAL3ST3 | c.440A>C p.Y147S | Missense Mutation (SNP) | VAF 59/411 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- KCNG1 | c.1408C>T p.L470F | Missense Mutation (SNP) | VAF 36/297 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MARCHF6 | c.2657A>C p.Q886P | Missense Mutation (SNP) | VAF 28/236 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.852); called by muse, mutect2, varscan2
- MYLK3 | c.385G>A p.G129R | Missense Mutation (SNP) | VAF 62/468 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- PHRF1 | c.3161C>T p.S1054F (on ENST00000264555 / NM_001286581.2; = p.S1053F on NM_020901.4) | Missense Mutation (SNP) | VAF 76/504 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PTEN | c.580_590del p.L194Dfs*4 | Frame Shift Del (DEL) | VAF 19/143 reads (13%) | called by mutect2, pindel, varscan2
- RIPOR2 | c.1209G>T p.K403N | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SLC2A13 | c.1216A>T p.I406F | Missense Mutation (SNP) | VAF 27/191 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SPAG5 | c.1478T>C p.M493T | Missense Mutation (SNP) | VAF 13/219 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2
- TMEM63A | c.1108_1117del p.C370Rfs*64 | Frame Shift Del (DEL) | VAF 16/109 reads (15%) | called by mutect2, pindel, varscan2
- UNC5D | c.1738T>A p.Y580N | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2
- ZNF827 | c.3173C>A p.T1058N | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2
- ACSM4 | c.564A>G p.K188= | Silent (SNP) | VAF 51/384 reads (13%) | called by muse, mutect2, varscan2
- ARHGEF3 | c.1285C>T p.L429= | Silent (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2
- BARHL1 | c.945C>G p.P315= | Silent (SNP) | VAF 13/112 reads (12%) | catalogued as rs550911455; called by muse, mutect2
- BCL11A | c.1575C>T p.S525= (on ENST00000335712 / NM_001365609.1; = p.S559= on NM_018014.4) | Silent (SNP) | VAF 47/302 reads (16%) | catalogued as COSV59624728; called by muse, mutect2, varscan2
- DCAF6 | c.45G>A p.R15= | Silent (SNP) | VAF 40/390 reads (10%) | catalogued as rs1228017790; called by muse, mutect2
- DDC | c.510G>A p.A170= | Silent (SNP) | VAF 86/576 reads (15%) | catalogued as rs774547345, COSV63563798; called by muse, mutect2, varscan2
- DNAH2 | c.6765C>T p.R2255= | Silent (SNP) | VAF 17/138 reads (12%) | called by muse, mutect2, varscan2
- FAM83B | c.3003A>G p.Q1001= | Silent (SNP) | VAF 11/86 reads (13%) | called by muse, mutect2, varscan2
- HMCN1 | c.3564G>A p.V1188= | Silent (SNP) | VAF 36/274 reads (13%) | catalogued as COSV54910297; called by muse, mutect2, varscan2
- KRT13 | c.1239C>T p.D413= | Silent (SNP) | VAF 54/552 reads (10%) | catalogued as rs552137773, COSV55840148; called by muse, mutect2
- LHX8 | c.747C>T p.N249= | Silent (SNP) | VAF 41/347 reads (12%) | catalogued as rs1209668255; called by muse, mutect2, varscan2
- PLCE1 | c.174C>T p.N58= | Silent (SNP) | VAF 85/504 reads (17%) | catalogued as rs761575973; called by muse, mutect2, varscan2
- POTEC | c.402C>T p.H134= | Silent (SNP) | VAF 101/787 reads (13%) | catalogued as rs748910521; called by muse, mutect2, varscan2
- RNF123 | c.1227C>T p.I409= | Silent (SNP) | VAF 46/333 reads (14%) | catalogued as rs746190835, COSV59684321; called by muse, mutect2, varscan2
- TMCO4 | c.861C>T p.L287= | Silent (SNP) | VAF 23/223 reads (10%) | catalogued as rs1267063539, COSV53876909; called by muse, mutect2, varscan2
- VCP | c.1086C>G p.R362= | Silent (SNP) | VAF 48/414 reads (12%) | called by muse, mutect2, varscan2
- VSIG1 | c.1068G>A p.S356= | Silent (SNP) | VAF 38/156 reads (24%) | catalogued as rs745893510; called by muse, mutect2, varscan2
- ZNF304 | c.1686T>C p.S562= | Silent (SNP) | VAF 29/241 reads (12%) | catalogued as rs756225586; called by muse, mutect2, varscan2
- ADGRE4P | n.2232A>C | RNA (SNP) | VAF 16/141 reads (11%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159728 C>T | 5'Flank (SNP) | VAF 41/325 reads (13%) | called by muse, mutect2, varscan2
